Gene-level copy-number profile of tumor specimen TARGET-40-PASKZZ-01A from TARGET case TARGET-40-PASKZZ, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.2 years (4,808 days).
Specimen TARGET-40-PASKZZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.2519b562-f63d-599c-a4b0-b9bcd65e201e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PASKZZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 443 have no estimate.
https://portal.gdc.cancer.gov/files/7b1979f8-f65d-44a9-80ee-e8098bc5404e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 233; copy number 2: 16,153; copy number 3: 26,456; copy number 4: 14,445; copy number 5: 885; copy number 6: 372; copy number 7: 290; copy number 8: 251; copy number 9: 58; copy number 10: 195; copy number 11: 300; copy number 12: 3; copy number 13: 7; copy number 15: 1; copy number 17: 2; copy number 19: 7.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,114 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,846,468–52,090,716, 39 genes, copy number 7: MRPS6P2, CDKN2C, MIR4421, MIR6500, C1orf185, Y_RNA, CFL1P2, LINC01562, RNF11, AL162430.1, AL162430.2, TTC39A, TTC39A-AS1, EPS15, AL671986.1, RNU6-877P, AC104170.1, EPS15-AS1, RNU6-1281P, CALR4P, OSBPL9, GAPDHP51, SLC25A6P3, AL050343.1, NRDC, AL050343.2, AL050343.3, MIR761, TSEN15P2, RAB3B, RNA5SP48, AL445685.2, RN7SL290P, TXNDC12, AL445685.3, KTI12, AL445685.1, TXNDC12-AS1, BTF3L4.
- chr1:56,994,778–67,259,979, 152 genes, copy number 8–19 (within-gene range 3–19) (broad region; genes not listed).
- chr1:67,522,299–72,753,772, 65 genes, copy number 10–17 (within-gene range 2–17) (broad region; genes not listed).
- chr1:72,636,547–80,646,791, 110 genes, copy number 7–15 (broad region; genes not listed).
- chr1:82,212,413–84,389,957, 18 genes, copy number 10 (within-gene range 3–10): AL157944.1, LINC01362, LINC01361, AC116099.1, LINC01712, LINC01725, AL035706.1, TTLL7, TTLL7-IT1, AC104454.1, AC104454.2, AL359504.1, PRKACB, TXN2P1, NEDD8P1, AL359273.1, SAMD13, AL359273.2.
- chr1:84,785,427–88,891,944, 61 genes, copy number 10 (broad region; genes not listed).
- chr1:91,260,766–91,404,856, 1 gene, copy number 10 (within-gene range 3–10): HFM1.
- chr1:91,328,369–95,278,940, 95 genes, copy number 8–10 (within-gene range 3–10) (broad region; genes not listed).
- chr1:98,660,388–99,244,794, 5 genes, copy number 9 (within-gene range 3–9): AC095031.1, SNX7, PLPPR5, AL445433.2, AL445433.1.
- chr1:103,523,562–110,023,742, 106 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr1:114,582,848–118,989,556, 83 genes, copy number 8–9 (within-gene range 3–9) (broad region; genes not listed).
- chr1:143,541,768–152,115,454, 305 genes, copy number 7–11 (broad region; genes not listed).
- chr1:153,534,599–153,726,353, 20 genes, copy number 7: S100A6, S100A5, S100A4, S100A3, S100A2, BX470102.2, S100A16, S100A14, S100A13, AL162258.1, S100A1, AL162258.2, CHTOP, SNAPIN, ILF2, NPR1, MIR8083, RN7SL372P, GEMIN2P1, Y_RNA.
- chr18:73,711,329–76,498,088, 54 genes, copy number 8: AC079070.1, RN7SL401P, AC090125.1, AC010947.1, AC090125.2, FBXO15, TIMM21, AC090398.1, RN7SL551P, CYB5A, AC090398.2, C18orf63, FAUP1, LINC01922, DIPK1C, AC009704.3, CNDP2, AC009704.2, CNDP1, AC009704.1, LINC00909, ZNF407, AC015819.2, AC015819.1, AC015819.4, AC015819.3, AC015819.5, ZADH2, TSHZ1, AC116003.3, AC116003.1, SMIM21, AC116003.2, AC012101.2, AC012101.1, AC090812.1, AC090338.1, LINC01898, AC021506.1, AC021506.2, AC090457.1, AC011095.1, AC103808.6, LINC01893, AC103808.2, AC103808.4, AC103808.3, AC103808.1, AC103808.5, ZNF516, AC009716.1, AC009716.2, AC018413.1, ZNF516-DT.

Autosomal genes at a single copy (total copy number 1): 233. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
